Somatic mutation profile of tumor specimen 0DWESA from CCDI case PBCPAR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.4 years (1,958 days).
Specimen 0DWESA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 10d3d406-98a4-4a96-b5f1-6ac1ab8c9460.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWES1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cbd807e6-dfc1-4128-b417-d18fcd9124fe

The open-access MAF lists 30 somatic variants for this specimen: 23 protein-altering or splice-affecting, 1 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Intron 4, Frame Shift Ins 2, 5'UTR 1, 3'UTR 1, Silent 1, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 145/322 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 22/278 reads (8%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 106/346 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, varscan2
- ADGRE3 | c.1222G>A p.V408M | Missense Mutation (SNP) | VAF 105/391 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.322); catalogued as rs202195537, COSV53729813; called by muse, mutect2, varscan2
- HDAC7 | c.2138G>A p.G713D (on ENST00000427332; = p.G752D on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/234 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50410412; called by muse, mutect2
- KLHL34 | c.1663C>T p.R555W | Missense Mutation (SNP) | VAF 42/349 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as rs914654948, COSV101070016; called by muse, mutect2, varscan2
- MARCHF9 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 42/130 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.54); catalogued as rs1270888665, COSV56984072; called by muse, mutect2, varscan2
- PES1 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 48/183 reads (26%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.589); catalogued as rs529713663, COSV100072953, COSV100073103; called by muse, mutect2, varscan2
- PHF5A | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 139/334 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.125); catalogued as COSV53439599; called by muse, mutect2, varscan2
- PTPRH | c.1975C>A p.L659I | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.233); catalogued as rs777120415; called by muse, mutect2, varscan2
- RYR1 | c.5891G>A p.R1964H | Missense Mutation (SNP) | VAF 153/358 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs767487116, COSV62090903, COSV62109928; called by muse, mutect2, varscan2
- STAG2 | c.3034C>T p.R1012* | Nonsense Mutation (SNP) | VAF 104/239 reads (44%) | catalogued as COSV54350913; called by muse, mutect2, varscan2
- SYCP1 | c.2864G>A p.R955H | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.649); catalogued as rs771129520, COSV65695325; called by muse, mutect2, varscan2
- ARHGEF33 | c.1881_1882dup p.P628Rfs*79 | Frame Shift Ins (INS) | VAF 63/280 reads (23%) | called by mutect2, pindel, varscan2
- CRISPLD1 | c.1021A>G p.I341V | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.181); called by muse, mutect2
- ENPP2 | c.1952G>T p.S651I (on ENST00000075322 / NM_001040092.3; = p.S703I on NM_006209.5) | Missense Mutation (SNP) | VAF 42/462 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2
- ETNK2 | c.202_203insA p.L68Hfs*60 | Frame Shift Ins (INS) | VAF 77/396 reads (19%) | called by mutect2, pindel, varscan2
- HSPA13 | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 137/515 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LIM2 | c.463A>T p.I155F (on ENST00000596399 / NM_001161748.2; = p.I197F on NM_030657.4) | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.691); called by muse, mutect2
- TLR3 | c.1630C>T p.R544W | Missense Mutation (SNP) | VAF 203/411 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- TUBGCP5 | c.2325A>G p.S775= | Splice Region (SNP) | VAF 48/151 reads (32%) | called by muse, mutect2, varscan2
- WNT3 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 12/359 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); called by muse, mutect2
- ZC3H7A | c.1643G>A p.G548D | Missense Mutation (SNP) | VAF 29/308 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2
- PARP2 | c.978A>G p.E326= | Silent (SNP) | VAF 17/182 reads (9%) | called by muse, mutect2, varscan2
- AK5 | c.891+38C>T | Intron (SNP) | VAF 80/179 reads (45%) | catalogued as rs1341963249, COSV60978348; called by muse, mutect2, varscan2
- ANKRD7 | c.-90C>T | 5'UTR (SNP) | VAF 18/35 reads (51%) | catalogued as rs781650587, COSV54554685; called by mutect2, varscan2
- FMNL3 | c.*8894G>A | 3'UTR (SNP) | VAF 6/51 reads (12%) | called by muse, mutect2
- GGA3 | c.1193-50G>A | Intron (SNP) | VAF 31/92 reads (34%) | called by muse, mutect2, varscan2
- IFT43 | c.296-5692C>A | Intron (SNP) | VAF 101/346 reads (29%) | called by muse, mutect2, varscan2
- IL17RC | c.340+77_340+85dup | Intron (INS) | VAF 25/114 reads (22%) | called by mutect2, varscan2
